Somatic mutation profile of tumor specimen TCGA-44-3919-01A (aliquot TCGA-44-3919-01A-02D-1458-08) from TCGA case TCGA-44-3919, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.4 years (26,081 days).
Specimen TCGA-44-3919-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 332e9129-de4d-4556-aed5-6d933a6f01a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3919-10A (Blood Derived Normal), aliquot TCGA-44-3919-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d6ba830-9507-4f57-b549-171e1b7019be

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 3, Intron 1, Splice Site 1, 5'UTR 1, In Frame Del 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 38/147 reads (26%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARHGEF28 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1279203645, COSV55264986, COSV55269258; called by muse, mutect2, varscan2
- ATG16L2 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as rs1565267692, COSV58362561; called by muse, mutect2, varscan2
- BRCA2 | c.10127C>G p.S3376* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as rs1555290049, COSV66337782; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2
- CAPZA2 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV63267285; called by muse, mutect2
- CCNI | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.166); catalogued as COSV99423602; called by muse, mutect2
- CEP97 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59126648; called by muse, mutect2, varscan2
- ESYT2 | c.1520C>A p.T507K (on ENST00000613624; = p.T431K on NM_020728.3) | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51754742; called by muse, mutect2, varscan2
- GLG1 | c.2847C>A p.F949L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); catalogued as rs746630548, COSV52671930; called by muse, mutect2, varscan2
- ITSN1 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67157438; called by muse, mutect2, varscan2
- MAF1 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59364041; called by muse, mutect2
- MC5R | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201991586, COSV61255313; called by muse, mutect2, varscan2
- MCF2 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58491366; called by muse, mutect2, varscan2
- MYH7B | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53423440; called by muse, mutect2, varscan2
- MYO18A | c.5734G>C p.E1912Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV62871131; called by muse, mutect2
- OPHN1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV62785198; called by muse, mutect2, varscan2
- PAQR9 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV61417486; called by muse, mutect2, varscan2
- PAX1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV68271127, COSV68271602; called by muse, mutect2, varscan2
- PLD2 | c.1536C>G p.S512R | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV54008166; called by muse, mutect2, varscan2
- PRDM16 | c.689T>C p.F230S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV54602637; called by muse, mutect2, varscan2
- PREPL | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752887453, COSV53218389; called by muse, mutect2, varscan2
- PTN | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV61967933; called by muse, mutect2, varscan2
- SLC26A3 | c.1588T>C p.Y530H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.942); catalogued as COSV60641726; called by muse, mutect2, varscan2
- UGT1A3 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 111/461 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs757870746, COSV59394925; called by muse, mutect2, varscan2
- WDR91 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs868274411, COSV60371322; called by muse, mutect2, varscan2
- ZDHHC8 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs750523517, COSV57712127; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100164322, COSV60872969; called by muse, mutect2
- ZNF558 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256254386, COSV56864045; called by muse, mutect2, varscan2
- KHNYN | c.1353del p.H451Qfs*27 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- MEPCE | c.1672-6_1684del p.X558_splice | Splice Site (DEL) | VAF 32/316 reads (10%) | called by mutect2, pindel
- PLEKHG7 | c.13_18del p.E5_S6del | In Frame Del (DEL) | VAF 20/106 reads (19%) | called by pindel, varscan2
- PPIG | c.1113_1146del p.M372Gfs*6 | Frame Shift Del (DEL) | VAF 14/147 reads (10%) | called by mutect2, pindel
- UXS1 | c.1066del p.D356Mfs*15 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel
- AATF | c.930A>G p.T310= | Silent (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- FILIP1 | c.612G>A p.L204= | Silent (SNP) | VAF 97/461 reads (21%) | catalogued as COSV52737158; called by muse, mutect2, varscan2
- FRYL | c.75T>G p.A25= | Silent (SNP) | VAF 50/188 reads (27%) | catalogued as COSV51956380; called by muse, mutect2, varscan2
- KIF22 | c.1986T>C p.C662= | Silent (SNP) | VAF 82/404 reads (20%) | catalogued as rs1156657476, COSV50717097; called by muse, mutect2, varscan2
- MAML3 | c.2724G>C p.G908= | Silent (SNP) | VAF 131/592 reads (22%) | catalogued as COSV72209799; called by muse, mutect2, varscan2
- NETO1 | c.1560T>C p.S520= | Silent (SNP) | VAF 40/235 reads (17%) | catalogued as COSV55011993; called by muse, mutect2, varscan2
- PCDHB11 | c.2214C>T p.D738= | Silent (SNP) | VAF 16/368 reads (4%) | catalogued as COSV61313256; called by muse, mutect2
- SH3PXD2B | c.2256G>A p.Q752= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs1488951850, COSV61128772; called by muse, mutect2, varscan2
- TMPRSS6 | c.2326C>T p.L776= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs756171282, COSV60982232; called by muse, mutect2, varscan2
- PLEKHG7 | c.-2T>C | 5'UTR (SNP) | VAF 22/111 reads (20%) | called by muse, varscan2
- TRIM61 | c.526-2276G>C | Intron (SNP) | VAF 6/116 reads (5%) | catalogued as COSV61418666; called by muse, mutect2
